Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A959, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A959-01A (Primary Tumor).

(MM/DD/YYYY)

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site: Cervix NOS
C53.9
9/23/12/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

“Uterine cervix biopsy”:

- Invasive poorly differentiated squamous cell carcinoma.

Criteria	lw 11/17/13	Yes	No

Source: NCI Genomic Data Commons file 394e9b25-e752-4a57-a650-dfe58e892c3f (TCGA-VS-A959.10A6CADD-C99B-4A34-9D5D-02AD37C1AB80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).